CCDI case PBBKSP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/00f4dd2d-11b7-4a97-b90e-8d4b56237652

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.0 years (1,816 days).

Biospecimens (3 samples)
- Sample 0DB11B: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB11G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DB11Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
